Somatic mutation profile of tumor specimen TCGA-AY-A69D-01A (aliquot TCGA-AY-A69D-01A-11D-A36X-10) from TCGA case TCGA-AY-A69D, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 55.6 years (20,299 days).
Specimen TCGA-AY-A69D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75387128-2757-4efe-9204-a4b35a60935b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AY-A69D-10A (Blood Derived Normal), aliquot TCGA-AY-A69D-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ecd2e08e-c9f9-4ff9-a7d9-790866844763

The open-access MAF lists 216 somatic variants for this specimen: 163 protein-altering or splice-affecting, 49 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 138, Silent 49, Nonsense Mutation 10, Frame Shift Ins 5, Splice Site 4, Frame Shift Del 3, Splice Region 2, Intron 1, 5'UTR 1, In Frame Del 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 101/251 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 83/190 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SLC20A2 | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs387906652, CM121619, CM121620, COSV60603043; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SOX9 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 30/82 reads (37%) | catalogued as rs886041242, CM941296, COSV55426731; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTL7B | c.1225G>A p.V409M | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs370958419; called by muse, mutect2, varscan2
- ADAMTS9 | c.1906T>C p.S636P | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.859); catalogued as COSV99899954; called by muse, mutect2, varscan2
- ADRA2B | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as rs768804034, COSV101337380; called by muse, mutect2, varscan2
- AMOT | c.1414G>A p.V472I (on ENST00000371959 / NM_001113490.1; = p.V63I on NM_133265.3) | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0.019); catalogued as rs41300179, COSV100495389; called by muse, mutect2, varscan2
- APOL1 | c.1007C>T p.T336M | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.224); catalogued as rs553515630, COSV59869634; called by muse, mutect2
- ATCAY | c.848T>A p.I283N | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100008924; called by muse, mutect2
- ATF2 | c.1231C>T p.L411F | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51372711; called by muse, mutect2, varscan2
- BRWD3 | c.4837T>G p.L1613V | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.055); catalogued as COSV100956340; called by muse, mutect2
- C7orf26 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1219187057, COSV100732970; called by muse, mutect2, varscan2
- CACNA1G | c.6901C>T p.R2301W | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs374573766; called by muse, mutect2, varscan2
- CARD6 | c.2009C>G p.S670C | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99621068; called by muse, mutect2, varscan2
- CC2D2A | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.747); catalogued as rs113371687, COSV67504728, COSV67505036; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCKBR | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 73/258 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV58098769; called by muse, mutect2, varscan2
- CEP120 | c.2859T>A p.D953E | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100071318; called by muse, mutect2
- CHD9 | c.6754A>G p.M2252V | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.615); catalogued as COSV99529495; called by muse, mutect2, varscan2
- CHRM1 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1476783014, COSV100186272; called by muse, mutect2, varscan2
- CLIP4 | c.529+2C>A p.X177_splice | Splice Site (SNP) | VAF 46/104 reads (44%) | catalogued as COSV100192208; called by muse, mutect2, varscan2
- CSMD3 | c.1211C>G p.S404* | Nonsense Mutation (SNP) | VAF 9/195 reads (5%) | catalogued as COSV52108624, COSV99842288; called by muse, mutect2
- CUL3 | c.2030-2A>G p.X677_splice | Splice Site (SNP) | VAF 131/331 reads (40%) | catalogued as COSV100024553; called by muse, mutect2, varscan2
- CYP4F2 | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99686206; called by muse, mutect2, varscan2
- DACT3 | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.566); catalogued as COSV56259596; called by muse, mutect2
- DAO | c.212C>G p.T71S | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.881); catalogued as COSV57323908; called by muse, mutect2, varscan2
- DCAF13 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as rs766382243, COSV99885306; called by muse, mutect2, varscan2
- DDX42 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as COSV100835001; called by muse, varscan2
- DDX54 | c.1239C>A p.Y413* | Nonsense Mutation (SNP) | VAF 32/116 reads (28%) | catalogued as COSV58375388; called by muse, mutect2, varscan2
- DEF8 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs756500620, COSV51918062; called by muse, mutect2, varscan2
- DENND11 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs761806017, COSV72097838; called by muse, mutect2, varscan2
- DMD | c.2992T>C p.Y998H | Missense Mutation (SNP) | VAF 105/494 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.847); catalogued as COSV63779381; called by muse, mutect2, varscan2
- DNAI3 | c.1832A>G p.N611S | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99642163; called by muse, mutect2, varscan2
- DNMBP | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs115222765, COSV100144182; called by muse, mutect2, varscan2
- DOCK11 | c.3647G>T p.S1216I | Missense Mutation (SNP) | VAF 77/289 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99354369; called by muse, mutect2, varscan2
- DPY19L1 | c.1101C>T p.D367= | Splice Region (SNP) | VAF 206/656 reads (31%) | catalogued as rs780746473, COSV100204865; called by muse, mutect2, varscan2
- DST | c.21658G>T p.V7220L (on ENST00000361203 / NM_001374722.1; = p.V4917L on NM_015548.5) | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55032530; called by muse, mutect2, varscan2
- DYSF | c.4267C>T p.R1423C | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs377706756; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EYS | c.162C>A p.Y54* | Nonsense Mutation (SNP) | VAF 22/109 reads (20%) | catalogued as CM1312777, COSV100676908; called by muse, mutect2, varscan2
- FAAP100 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777046070, COSV100585511; called by muse, mutect2, varscan2
- FAT1 | c.12819C>A p.F4273L | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.986); catalogued as COSV71672201, COSV71672221; called by muse, mutect2, varscan2
- FAT1 | c.10504G>A p.A3502T | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV101499512; called by muse, mutect2, varscan2
- FAT1 | c.10067C>T p.T3356M | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.56); catalogued as rs760734038, COSV71671884; called by muse, mutect2, varscan2
- FAT3 | c.5684C>A p.P1895H | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53155882; called by muse, mutect2, varscan2
- FBLN1 | c.1055C>T p.T352M | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs540607391, COSV53045235; called by muse, mutect2
- FBXO47 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.368); catalogued as COSV65242485; called by muse, mutect2, varscan2
- FEM1B | c.1582G>A p.V528M | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.121); catalogued as rs757432489, COSV60989298; called by muse, mutect2, varscan2
- FLT4 | c.2350G>A p.V784I | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); catalogued as rs757057248, COSV56098792; called by muse, varscan2
- FOXP2 | c.987C>A p.D329E | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.417); catalogued as COSV100647154; called by muse, mutect2, varscan2
- FRMPD3 | c.2241G>T p.Q747H | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV52195507; called by muse, mutect2, varscan2
- FRRS1L | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.105); catalogued as COSV101643930; called by muse, mutect2, varscan2
- FRY | c.2281G>A p.V761I | Missense Mutation (SNP) | VAF 86/229 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs758925707, COSV66565160; called by muse, mutect2
- FSD2 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149195634, COSV100575236; called by muse, mutect2, varscan2
- GAK | c.2249G>A p.G750E | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100033909; called by muse, mutect2, varscan2
- GALNT18 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99924776, COSV99925399; called by muse, mutect2, varscan2
- GATA3 | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771315353, COSV60515507, COSV60517246, COSV60518853; called by muse, mutect2, varscan2
- GLT1D1 | c.350T>C p.M117T | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV55885752; called by muse, mutect2, varscan2
- GPR157 | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.963); catalogued as rs374315465; called by muse, mutect2, varscan2
- HROB | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55370351; called by muse, mutect2, varscan2
- IGHV3-21 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs562543291; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1845G>T p.R615S | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100781730, COSV61151281; called by muse, mutect2, varscan2
- ITGA6 | c.1898G>A p.R633H (on ENST00000442250; = p.R594H on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs754282661, COSV51226071; called by muse, mutect2, varscan2
- JAM2 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.552); catalogued as rs550982612, COSV57259253; called by muse, mutect2, varscan2
- KAT6B | c.1462A>G p.K488E | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.169); catalogued as COSV99768675; called by muse, mutect2, varscan2
- KAT7 | c.149G>T p.S50I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99371986; called by muse, mutect2, varscan2
- KCNS2 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370705767; called by muse, mutect2, varscan2
- KDSR | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141264328; called by muse, mutect2, varscan2
- KIF17 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs138004364; called by muse, mutect2, varscan2
- KIF26A | c.2419G>A p.D807N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1483419517, COSV100181428; called by muse, mutect2, varscan2
- KIF5C | c.152G>A p.R51K | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV70535492, COSV70537284; called by muse, varscan2
- KMT2C | c.9235C>T p.R3079* | Nonsense Mutation (SNP) | VAF 75/178 reads (42%) | catalogued as COSV51430355; called by muse, mutect2, varscan2
- KRT32 | c.871-1G>T p.X291_splice | Splice Site (SNP) | VAF 45/103 reads (44%) | catalogued as COSV56787439; called by muse, mutect2, varscan2
- KRT6C | c.254G>T p.S85I | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV99360117; called by muse, mutect2, varscan2
- LAMA1 | c.5609G>A p.R1870K | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV101057177; called by muse, mutect2, varscan2
- LAMA4 | c.2900C>T p.S967L (on ENST00000230538 / NM_001105206.3; = p.S960L on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs782682713, COSV57901390; called by muse, mutect2, varscan2
- LGALS3 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); catalogued as COSV99582498; called by muse, mutect2
- LRP1 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54504237; called by muse, mutect2, varscan2
- LRP1B | c.8600G>C p.G2867A | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101258934; called by muse, mutect2
- LRRK1 | c.2446C>T p.R816* | Nonsense Mutation (SNP) | VAF 21/41 reads (51%) | catalogued as rs766532218, COSV52610706; called by muse, mutect2, varscan2
- MAP2K2 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233377512, COSV53571217; called by muse, mutect2, varscan2
- MAP3K14 | c.1780C>T p.H594Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100766527; called by muse, mutect2, varscan2
- MC3R | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.673); catalogued as COSV54764667; called by muse, mutect2, varscan2
- MCM7 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as rs767546167, COSV100385072; called by muse, mutect2, varscan2
- MCPH1 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.58); PolyPhen benign (0.138); catalogued as COSV60917915; called by muse, mutect2, varscan2
- MLC1 | c.1111G>A p.V371I | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs200273593, COSV61116031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MPO | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as rs565563391, COSV56564733, COSV99832935; called by muse, mutect2, varscan2
- MPP2 | c.533C>T p.T178M (on ENST00000461854 / NM_001278372.2; = p.T154M on NM_005374.5) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779453977, COSV52238854, COSV52240628; called by muse, mutect2, varscan2
- MSX1 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as COSV101235736; called by muse, mutect2, varscan2
- MUC5B | c.6266C>T p.T2089M | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs377736509; called by muse, mutect2, varscan2
- NBEAL2 | c.4091G>T p.S1364I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV99436964; called by muse, mutect2, varscan2
- NEXN | c.201G>A p.W67* | Nonsense Mutation (SNP) | VAF 47/166 reads (28%) | catalogued as rs999958582, COSV99630540; called by muse, mutect2, varscan2
- NFATC1 | c.841C>G p.H281D | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV53706379; called by muse, mutect2, varscan2
- NLRP7 | c.1746G>T p.E582D | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.554); catalogued as COSV60179351; called by muse, mutect2, varscan2
- NRXN1 | c.2317G>T p.A773S | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.087); catalogued as rs199548487, COSV58445112, COSV58479572; called by muse, mutect2, varscan2
- NTN5 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs761654700, COSV99539519; called by muse, mutect2, varscan2
- NYNRIN | c.5564G>A p.R1855Q | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.884); catalogued as rs775892926, COSV66844538, COSV66844849; called by muse, mutect2, varscan2
- OBSCN | c.15348G>C p.L5116F | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV99482215; called by muse, mutect2, varscan2
- OTC | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 62/295 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.213); catalogued as COSV99234287; called by muse, mutect2, varscan2
- PC | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.206); catalogued as COSV100540859; called by muse, mutect2, varscan2
- PCDH8 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.069); catalogued as rs866733795, COSV100131455, COSV100131624; called by muse, mutect2, varscan2
- PCLO | c.15319A>T p.M5107L | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV61656636; called by muse, mutect2
- PELO | c.331A>T p.T111S | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.088); catalogued as COSV50892395; called by muse, mutect2, varscan2
- PEX5 | c.1091A>G p.Q364R (on ENST00000420616; = p.Q356R on NM_000319.5) | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.053); catalogued as COSV99871172; called by muse, mutect2, varscan2
- PFAS | c.3790G>A p.G1264R | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs537007406, COSV58982421; called by muse, mutect2, varscan2
- PHF21B | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (1); PolyPhen possibly damaging (0.446); catalogued as COSV100504005; called by muse, mutect2
- PIK3CA | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 165/386 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV55921652; called by muse, mutect2, varscan2
- PLEKHM1 | c.450G>T p.Q150H | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.409); catalogued as rs1327013073, COSV69599301; called by muse, mutect2, varscan2
- PPM1D | c.1535dup p.N512Kfs*16 | Frame Shift Ins (INS) | VAF 46/95 reads (48%) | catalogued as rs763475304; called by mutect2, varscan2
- PPP1R26 | c.2783C>G p.P928R | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV100778121, COSV63354767; called by muse, mutect2, varscan2
- RASL12 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs138898900, COSV99584856; called by muse, mutect2, varscan2
- RNF138 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1422182371, COSV55234116; called by muse, mutect2, varscan2
- RYR3 | c.6801-1G>T p.X2267_splice (on ENST00000389232; = p.S2268I on NM_001036.6) | Splice Site (SNP) | VAF 19/51 reads (37%) | catalogued as COSV100774403; called by muse, mutect2, varscan2
- SCAMP5 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.168); catalogued as rs769826771, COSV61625550; called by muse, mutect2, varscan2
- SCAP | c.1655C>T p.P552L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV99652694; called by muse, mutect2, varscan2
- SEC16A | c.3974C>T p.T1325M | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs759715457, COSV51536937; called by muse, mutect2, varscan2
- SEMA4G | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs528948930, COSV99272556; called by muse, mutect2, varscan2
- SETD2 | c.6038T>C p.L2013P | Missense Mutation (SNP) | VAF 125/202 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57456432; called by muse, mutect2, varscan2
- SF3B4 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV54965225; called by muse, mutect2
- SHC3 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV65436714; called by muse, mutect2, varscan2
- SIX5 | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs768789921, COSV99353503; called by muse, mutect2, varscan2
- SLC1A3 | c.1168G>A p.V390M | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1200209870, COSV99467994; called by muse, mutect2, varscan2
- SLC3A2 | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100101478; called by muse, varscan2
- SLC41A3 | c.1019A>G p.Y340C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV59989767; called by muse, mutect2, varscan2
- SMARCA2 | c.2252T>C p.M751T | Missense Mutation (SNP) | VAF 49/75 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV61810849; called by muse, varscan2
- TAS1R2 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.085); catalogued as rs957935285, COSV64747781; called by muse, mutect2, varscan2
- TBC1D8B | c.2204C>A p.T735N | Missense Mutation (SNP) | VAF 98/419 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs147581665, COSV99344830; called by muse, mutect2, varscan2
- TCF20 | c.2704C>T p.P902S | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.604); catalogued as COSV100166811; called by muse, mutect2, varscan2
- TFAP2D | c.351C>A p.H117Q | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.212); catalogued as COSV99146442; called by muse, mutect2, varscan2
- TIAM2 | c.2707G>T p.G903W | Missense Mutation (SNP) | VAF 54/403 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100019674; called by muse, mutect2, varscan2
- TMEM161A | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs200635309, COSV99365540; called by muse, mutect2, varscan2
- TMOD1 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52251299; called by muse, mutect2, varscan2
- TNRC6C | c.4545G>A p.W1515* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100050435; called by muse, mutect2, varscan2
- TRAF2 | c.1057G>A p.V353I | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV56040406; called by muse, mutect2, varscan2
- TRAF7 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.102); catalogued as rs766294780, COSV58216325; called by muse, mutect2, varscan2
- TRDN | c.1717dup p.T573Nfs*11 | Frame Shift Ins (INS) | VAF 22/66 reads (33%) | catalogued as rs1224610838; called by mutect2, pindel, varscan2
- TRPC4AP | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs752598929, COSV99328732; called by muse, mutect2, varscan2
- TXLNB | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 35/303 reads (12%) | catalogued as COSV100625112; called by muse, mutect2, varscan2
- UBR4 | c.6079G>A p.D2027N | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV100921397; called by muse, mutect2
- UNC13C | c.4713G>A p.P1571= | Splice Region (SNP) | VAF 22/67 reads (33%) | catalogued as rs1445102357, COSV52841330; called by muse, mutect2, varscan2
- USP43 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as rs1333072106, COSV99556925; called by muse, mutect2, varscan2
- USP6 | c.3752dup p.S1252Qfs*12 | Frame Shift Ins (INS) | VAF 19/164 reads (12%) | catalogued as rs754083634; called by mutect2, varscan2
- WHRN | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs372230625; called by muse, mutect2, varscan2
- ZBTB33 | c.1447C>A p.H483N | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100434264; called by muse, mutect2, varscan2
- ZIK1 | c.1335C>G p.S445R | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.97); catalogued as COSV100277603; called by muse, mutect2, varscan2
- ZNF107 | c.652T>C p.Y218H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV100788449; called by muse, mutect2, varscan2
- ZNF112 | c.432G>T p.W144C (on ENST00000337401 / NM_001083335.2; = p.W138C on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV100496103; called by muse, mutect2, varscan2
- ZNF211 | c.746G>T p.R249I (on ENST00000347302 / NM_198855.4; = p.R262I on NM_006385.5) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as COSV99560392; called by muse, mutect2, varscan2
- ZNF404 | c.317G>T p.C106F | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.068); catalogued as COSV100182715; called by muse, mutect2, varscan2
- ZNF490 | c.1300C>T p.R434* | Nonsense Mutation (SNP) | VAF 58/129 reads (45%) | catalogued as rs1308333348, COSV61007227; called by muse, mutect2, varscan2
- ZNF586 | c.251G>C p.G84A | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.074); catalogued as rs1034981414, COSV101197715, COSV66972692; called by muse, mutect2, varscan2
- ZNF808 | c.907A>C p.T303P | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.818); catalogued as COSV100708116; called by muse, mutect2, varscan2
- ZNF85 | c.1153C>A p.L385I | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60215456; called by muse, mutect2, varscan2
- ZNFX1 | c.1008G>A p.M336I | Missense Mutation (SNP) | VAF 90/287 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1446042056, COSV65578012; called by muse, mutect2, varscan2
- ZSCAN18 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1330853622, COSV99559617; called by muse, mutect2, varscan2
- ZSCAN20 | c.1759C>T p.L587F | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV100792693; called by muse, mutect2, varscan2
- ZSWIM8 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs1460994788, COSV67133997; called by muse, mutect2, varscan2
- ZXDA | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.108); catalogued as rs1360105670, COSV100699448; called by muse, mutect2, varscan2
- APC | c.2327_2328insCT p.D777* | Frame Shift Ins (INS) | VAF 26/80 reads (33%) | called by mutect2, pindel, varscan2
- APC | c.4219_4220del p.S1407* | Frame Shift Del (DEL) | VAF 34/127 reads (27%) | called by pindel, varscan2
- ARID1B | c.5108dup p.R1704Kfs*4 | Frame Shift Ins (INS) | VAF 38/101 reads (38%) | called by pindel, varscan2
- CAMTA2 | c.1294_1300del p.S432Qfs*49 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | called by mutect2, pindel, varscan2
- CSN2 | c.470_475del p.I157_Q159delinsK | In Frame Del (DEL) | VAF 51/108 reads (47%) | called by mutect2, pindel, varscan2
- ELP1 | c.241del p.E81Sfs*28 | Frame Shift Del (DEL) | VAF 24/78 reads (31%) | called by mutect2, pindel, varscan2
- ANKRD55 | c.1026G>A p.R342= | Silent (SNP) | VAF 60/175 reads (34%) | catalogued as rs1458294191, COSV100591299; called by muse, mutect2, varscan2
- ARID3B | c.1026G>A p.A342= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as rs757566083, COSV60558701; called by muse, mutect2, varscan2
- CNTNAP1 | c.1707G>A p.T569= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs138190887; called by muse, mutect2, varscan2
- CPAMD8 | c.4722C>T p.S1574= (on ENST00000651564; = p.S1527= on NM_015692.5) | Silent (SNP) | VAF 18/126 reads (14%) | catalogued as rs531700758, COSV101488551; called by muse, mutect2, varscan2
- CYC1 | c.30G>A p.G10= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV100010534; called by muse, mutect2
- DLG3 | c.978C>T p.Y326= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as rs370555109, COSV52079971; called by muse, mutect2, varscan2
- DMRT1 | c.135G>A p.S45= | Silent (SNP) | VAF 37/52 reads (71%) | catalogued as rs752339043, COSV101206693; called by muse, mutect2, varscan2
- DNAH5 | c.11586G>A p.P3862= | Silent (SNP) | VAF 64/134 reads (48%) | catalogued as rs755874851, COSV54218580; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- DUOX1 | c.4206G>T p.L1402= | Silent (SNP) | VAF 36/68 reads (53%) | catalogued as COSV99334666; called by muse, mutect2, varscan2
- EPHB1 | c.192C>T p.F64= | Silent (SNP) | VAF 46/104 reads (44%) | catalogued as rs755589996, COSV101213926, COSV67661817; called by muse, mutect2, varscan2
- EXOC3L4 | c.1830C>A p.A610= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV66295834, COSV66295931; called by muse, mutect2, varscan2
- FBLN1 | c.84C>T p.D28= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs754024808, COSV53051778; called by muse, mutect2, varscan2
- FBXW10 | c.906C>T p.A302= | Silent (SNP) | VAF 136/380 reads (36%) | catalogued as rs746487298, COSV100111622; called by muse, mutect2, varscan2
- FBXW10 | c.1590G>A p.T530= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as rs765147247, COSV100111632; called by muse, mutect2, varscan2
- FMO2 | c.1098C>T p.L366= | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as rs771519694, COSV52947872; called by muse, mutect2, varscan2
- FXR1 | c.1849C>T p.L617= | Silent (SNP) | VAF 61/211 reads (29%) | catalogued as COSV99976560; called by muse, mutect2, varscan2
- FZD9 | c.984G>A p.S328= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV100750886; called by muse, mutect2, varscan2
- GPLD1 | c.1239C>T p.I413= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs375629493; called by muse, mutect2, varscan2
- IBA57 | c.639C>T p.L213= | Silent (SNP) | VAF 36/64 reads (56%) | catalogued as rs751616087, COSV100812776; called by muse, mutect2, varscan2
- ITPR1 | c.6543C>T p.D2181= (on ENST00000354582; = p.D2126= on NM_002222.7) | Silent (SNP) | VAF 62/143 reads (43%) | catalogued as rs578051224, COSV56990162; called by muse, mutect2, varscan2
- KDM2B | c.2388C>T p.D796= | Silent (SNP) | VAF 35/74 reads (47%) | catalogued as rs782808062, COSV100997406, COSV65641046; called by muse, mutect2
- KIAA1841 | c.195T>G p.P65= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV99694045; called by muse, mutect2
- KLF1 | c.576G>A p.A192= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV99322465; called by muse, mutect2, varscan2
- MAPK4 | c.1590C>T p.D530= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs1234966576, COSV68542229; called by muse, mutect2, varscan2
- MAPK8IP2 | c.579C>T p.P193= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs749260984, COSV99151325; called by muse, mutect2, varscan2
- MBD3 | c.150G>A p.A50= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs149431650; called by muse, mutect2, varscan2
- MYO9B | c.3801C>T p.S1267= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as rs369057835; called by muse, mutect2, varscan2
- NAPRT | c.681C>T p.D227= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99435226; called by muse, mutect2, varscan2
- NLRP14 | c.2163C>A p.I721= | Silent (SNP) | VAF 49/242 reads (20%) | catalogued as COSV100205267; called by muse, mutect2, varscan2
- NLRP7 | c.1284C>T p.S428= | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as COSV60173605; called by muse, mutect2, varscan2
- OR5J2 | c.264G>T p.V88= | Silent (SNP) | VAF 101/214 reads (47%) | catalogued as COSV56621985; called by muse, mutect2, varscan2
- PABPC4 | c.1455C>T p.A485= | Silent (SNP) | VAF 34/61 reads (56%) | catalogued as rs1331044643, COSV63293668; called by muse, mutect2, varscan2
- PC | c.2250G>T p.T750= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100547154; called by muse, mutect2, varscan2
- POLR3A | c.778T>C p.L260= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV100965763; called by muse, mutect2, varscan2
- PRMT8 | c.666C>T p.Y222= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as rs763610227, COSV54214584, COSV99713579; called by muse, mutect2, varscan2
- PTPRT | c.1656C>A p.L552= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as rs371999348, COSV100624528; called by muse, mutect2, varscan2
- PYHIN1 | c.1452C>A p.S484= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV100932642, COSV100932662; called by muse, mutect2, varscan2
- RAB9B | c.81C>T p.Y27= | Silent (SNP) | VAF 30/168 reads (18%) | catalogued as rs141822799, COSV54587221; called by muse, mutect2, varscan2
- RAD52 | c.702G>A p.P234= | Silent (SNP) | VAF 26/148 reads (18%) | catalogued as rs905533800, COSV57273119; called by muse, mutect2, varscan2
- SGO2 | c.3742A>C p.R1248= | Silent (SNP) | VAF 26/356 reads (7%) | catalogued as COSV100764750; called by muse, mutect2
- SMARCA4 | c.4329C>T p.R1443= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs373999751; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPRY4 | c.639G>A p.E213= (on ENST00000434127 / NM_001127496.3; = p.E236= on NM_030964.4) | Silent (SNP) | VAF 37/97 reads (38%) | catalogued as COSV100702220; called by muse, mutect2, varscan2
- TDGF1 | c.510A>T p.A170= | Silent (SNP) | VAF 48/85 reads (56%) | catalogued as COSV99947568; called by muse, mutect2, varscan2
- TRIM42 | c.963C>T p.H321= | Silent (SNP) | VAF 84/202 reads (42%) | catalogued as rs973883247, COSV53880614; called by muse, mutect2, varscan2
- TTLL13P | c.768C>T p.D256= | Silent (SNP) | VAF 37/138 reads (27%) | catalogued as COSV100296667; called by muse, mutect2
- USO1 | c.1842G>A p.T614= | Silent (SNP) | VAF 60/183 reads (33%) | catalogued as rs761243010, COSV99363033; called by muse, mutect2, varscan2
- ZAP70 | c.267C>T p.R89= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs777171551, COSV53852737; called by muse, mutect2, varscan2
- ZNF264 | c.1545G>A p.E515= | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as rs1006792912, COSV99567369; called by muse, mutect2, varscan2
- ZNF808 | c.2400C>T p.F800= | Silent (SNP) | VAF 31/183 reads (17%) | catalogued as COSV100707795, COSV63119513; called by muse, mutect2, varscan2
- COPS9 | c.-1G>A | 5'UTR (SNP) | VAF 21/119 reads (18%) | catalogued as rs1196556700, COSV100108887; called by muse, mutect2, varscan2
- MACF1 | c.15832-11543C>T | Intron (SNP) | VAF 12/182 reads (7%) | catalogued as COSV57136518; called by muse, mutect2
- MIR518C | n.100G>T | RNA (SNP) | VAF 25/93 reads (27%) | called by muse, varscan2
- N4BP2L2 | chr13:32442761 T>C | 3'Flank (SNP) | VAF 35/158 reads (22%) | catalogued as COSV62634644; called by muse, mutect2, varscan2
